Somatic mutation profile of tumor specimen TCGA-12-0818-01A (aliquot TCGA-12-0818-01A-01W-0424-08) from TCGA case TCGA-12-0818, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 45.6 years (16,666 days).
Specimen TCGA-12-0818-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bf329ad3-d09d-4bd3-b41b-e8a653e510b2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-12-0818-10A (Blood Derived Normal), aliquot TCGA-12-0818-10A-01W-0424-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6b5d4411-63ed-42dd-95fa-cd55b7c168ce

The open-access MAF lists 71 somatic variants for this specimen: 56 protein-altering or splice-affecting, 13 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 48, Silent 13, Nonsense Mutation 4, Frame Shift Del 3, Intron 1, 5'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 814/1220 reads (67%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.03); PolyPhen benign (0.1); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 176/210 reads (84%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACSM1 | c.1470G>T p.E490D | Missense Mutation (SNP) | VAF 67/629 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.378); catalogued as COSV99533023; called by muse, mutect2, varscan2
- AKAP3 | c.1765del p.D589Tfs*2 | Frame Shift Del (DEL) | VAF 1855/3842 reads (48%) | catalogued as COSV57421871; called by mutect2, pindel, varscan2
- ARID1B | c.4356G>T p.W1452C | Missense Mutation (SNP) | VAF 29/51 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV99269645; called by muse, mutect2, varscan2
- ASH2L | c.1858G>A p.G620R | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99166985; called by muse, mutect2, varscan2
- BCOR | c.2720G>A p.S907N | Missense Mutation (SNP) | VAF 119/206 reads (58%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV60723175; called by muse, mutect2, varscan2
- BLK | c.434C>T p.A145V | Missense Mutation (SNP) | VAF 758/1912 reads (40%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV52049064; called by muse, mutect2, varscan2
- CACNA2D3 | c.1817A>G p.Y606C | Missense Mutation (SNP) | VAF 54/356 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.88); catalogued as COSV99874056; called by muse, mutect2, varscan2
- CASP14 | c.202T>A p.F68I | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99693046; called by muse, mutect2
- CD163 | c.614C>T p.A205V | Missense Mutation (SNP) | VAF 453/1138 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.078); catalogued as COSV63130215; called by muse, mutect2, varscan2
- CEP104 | c.1924G>T p.A642S | Missense Mutation (SNP) | VAF 6/143 reads (4%) | SIFT tolerated (0.42); PolyPhen benign (0.011); catalogued as COSV100986627; called by muse, mutect2
- CFAP53 | c.1366G>T p.A456S | Missense Mutation (SNP) | VAF 175/566 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0.031); catalogued as COSV101274991; called by muse, mutect2, varscan2
- CTPS1 | c.20C>A p.T7N | Missense Mutation (SNP) | VAF 77/182 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as COSV101009342; called by muse, mutect2, varscan2
- CXCR3 | c.205C>A p.L69M | Missense Mutation (SNP) | VAF 39/223 reads (17%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.98); catalogued as COSV101031636; called by muse, mutect2, varscan2
- ETNPPL | c.1120G>T p.D374Y | Missense Mutation (SNP) | VAF 75/359 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV56596205, COSV99625277; called by muse, mutect2, varscan2
- FAM234A | c.1180G>A p.D394N | Missense Mutation (SNP) | VAF 66/83 reads (80%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as rs772106861, COSV51453284, COSV99395824; called by muse, mutect2, varscan2
- FKBP6 | c.467C>G p.A156G | Missense Mutation (SNP) | VAF 199/509 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0.055); catalogued as COSV99333989; called by muse, mutect2, varscan2
- FLG | c.4679G>A p.R1560H | Missense Mutation (SNP) | VAF 31/209 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs376401439; called by muse, mutect2, varscan2
- GALR1 | c.277G>T p.A93S | Missense Mutation (SNP) | VAF 57/339 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.054); catalogued as COSV100231852; called by muse, mutect2, varscan2
- GPHN | c.1144G>C p.D382H (on ENST00000315266 / NM_001377519.1; = p.D415H on NM_020806.5) | Missense Mutation (SNP) | VAF 32/486 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100016421; called by muse, mutect2
- GSDMB | c.235+1G>A p.X79_splice | Splice Site (SNP) | VAF 39/256 reads (15%) | catalogued as COSV100401538; called by muse, mutect2, varscan2
- HPS5 | c.3122C>T p.T1041M (on ENST00000349215 / NM_181507.2; = p.T927M on NM_007216.4) | Missense Mutation (SNP) | VAF 87/212 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as rs371347052, COSV100752292; called by muse, varscan2
- HYDIN | c.6643G>A p.V2215M | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as rs555322962, COSV59248366, COSV59264356; called by muse, mutect2, varscan2
- KCTD3 | c.262G>A p.V88M | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.82); catalogued as COSV99379324; called by muse, mutect2, varscan2
- KIF17 | c.658A>G p.M220V | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV99929128; called by muse, mutect2, varscan2
- KRT18 | c.857C>A p.S286Y | Missense Mutation (SNP) | VAF 28/237 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.751); catalogued as COSV66315735; called by muse, mutect2, varscan2
- LAMB2 | c.3514C>T p.R1172C | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754616119, COSV59734287; called by muse, mutect2, varscan2
- LRBA | c.6988G>A p.G2330R | Missense Mutation (SNP) | VAF 55/140 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99075048; called by muse, mutect2, varscan2
- MAPK3 | c.138G>C p.Q46H | Missense Mutation (SNP) | VAF 43/69 reads (62%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV99531639; called by muse, mutect2, varscan2
- MED12L | c.3943C>G p.L1315V | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV99853330; called by muse, mutect2, varscan2
- MED13 | c.2363A>G p.N788S | Missense Mutation (SNP) | VAF 6/77 reads (8%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.97); catalogued as rs1260954299, COSV101181111; called by muse, mutect2
- NEK10 | c.824G>A p.R275H | Missense Mutation (SNP) | VAF 9/101 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs768893065, COSV100411907; called by muse, mutect2, varscan2
- NOS2 | c.3425C>T p.A1142V | Missense Mutation (SNP) | VAF 93/498 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs200748226; called by muse, mutect2, varscan2
- OR10A3 | c.316C>T p.L106F | Missense Mutation (SNP) | VAF 95/362 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs760934508, COSV100660278; called by mutect2, varscan2
- OR5K4 | c.161G>A p.R54H | Missense Mutation (SNP) | VAF 136/600 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs201188789; called by muse, mutect2, varscan2
- PAPPA | c.510C>G p.Y170* | Nonsense Mutation (SNP) | VAF 191/966 reads (20%) | catalogued as rs775891849, COSV100074277; called by muse, mutect2, varscan2
- PLA2G7 | c.663G>T p.Q221H | Missense Mutation (SNP) | VAF 498/1358 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99221402; called by muse, mutect2, varscan2
- PTGFRN | c.1744C>T p.R582C | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as rs1410831066, COSV67798915; called by muse, mutect2, varscan2
- PTPN4 | c.2454G>T p.W818C | Missense Mutation (SNP) | VAF 59/986 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55310740; called by muse, mutect2
- PUM2 | c.1244C>T p.A415V | Missense Mutation (SNP) | VAF 32/63 reads (51%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0.005); catalogued as rs936041918, COSV100163695; called by muse, mutect2, varscan2
- RASGRF1 | c.2920G>T p.E974* | Nonsense Mutation (SNP) | VAF 52/1538 reads (3%) | catalogued as COSV101174530; called by muse, mutect2
- RNF128 | c.529A>G p.T177A (on ENST00000255499 / NM_194463.2; = p.T151A on NM_024539.3) | Missense Mutation (SNP) | VAF 43/131 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.052); catalogued as rs755237340, COSV99718218; called by muse, mutect2, varscan2
- SDS | c.786G>T p.E262D | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.781); catalogued as rs144503922; called by muse, mutect2
- SIRPG | c.938G>T p.W313L | Missense Mutation (SNP) | VAF 14/329 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.075); catalogued as COSV99403783; called by muse, mutect2
- SORBS1 | c.3387G>T p.R1129S | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.115); catalogued as COSV99528105; called by muse, mutect2, varscan2
- SUGP1 | c.1381C>T p.H461Y | Missense Mutation (SNP) | VAF 39/214 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.959); catalogued as rs1456634075, COSV99895134; called by muse, mutect2, varscan2
- SYNJ2 | c.4384G>T p.E1462* | Nonsense Mutation (SNP) | VAF 15/177 reads (8%) | catalogued as COSV100840244, COSV62899941; called by muse, mutect2
- TCF20 | c.4565C>T p.S1522L | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.084); catalogued as rs752102253, COSV100166606; called by muse, mutect2, varscan2
- TEKT4 | c.147T>A p.Y49* | Nonsense Mutation (SNP) | VAF 31/79 reads (39%) | catalogued as COSV99726409; called by muse, mutect2, varscan2
- TPR | c.94C>G p.Q32E | Missense Mutation (SNP) | VAF 130/171 reads (76%) | SIFT tolerated (0.25); PolyPhen benign (0.437); catalogued as COSV55219511, COSV99834352; called by muse, mutect2, varscan2
- USP31 | c.2901C>A p.S967R | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.001); catalogued as COSV99565293; called by muse, mutect2, varscan2
- ATRX | c.3874del p.S1292Qfs*54 | Frame Shift Del (DEL) | VAF 58/234 reads (25%) | called by pindel, varscan2
- CYFIP1 | c.1397G>C p.G466A | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.71); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- DTX4 | c.1381A>G p.S461G | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by mutect2, varscan2
- OGFR | c.330del p.I110Mfs*33 | Frame Shift Del (DEL) | VAF 13/96 reads (14%) | called by mutect2, pindel, varscan2
- ARSD | c.1521C>T p.G507= | Silent (SNP) | VAF 23/63 reads (37%) | catalogued as rs375430014, COSV66973287; called by muse, mutect2, varscan2
- ATP6AP2 | c.787T>C p.L263= | Silent (SNP) | VAF 30/86 reads (35%) | catalogued as COSV101011511; called by muse, mutect2, varscan2
- CACNA1F | c.3375G>A p.A1125= | Silent (SNP) | VAF 66/1268 reads (5%) | catalogued as rs147312871, COSV59904098; called by muse, mutect2
- CPXCR1 | c.523C>A p.R175= | Silent (SNP) | VAF 10/77 reads (13%) | catalogued as COSV52161589, COSV99342231; called by muse, mutect2, varscan2
- IFRD2 | c.495G>T p.L165= | Silent (SNP) | VAF 6/146 reads (4%) | catalogued as COSV100269527; called by muse, mutect2
- MKX | c.1014A>T p.I338= | Silent (SNP) | VAF 77/311 reads (25%) | catalogued as COSV101008780; called by muse, mutect2, varscan2
- NEXMIF | c.3939T>C p.F1313= | Silent (SNP) | VAF 226/800 reads (28%) | catalogued as COSV99280923; called by muse, mutect2, varscan2
- PRAG1 | c.564G>T p.V188= | Silent (SNP) | VAF 7/44 reads (16%) | catalogued as COSV100422227; called by muse, mutect2, varscan2
- ROCK1 | c.1134A>G p.E378= | Silent (SNP) | VAF 70/289 reads (24%) | catalogued as COSV101296402; called by muse, mutect2, varscan2
- ROR1 | c.393C>T p.C131= | Silent (SNP) | VAF 263/632 reads (42%) | catalogued as rs148616064; called by muse, mutect2, varscan2
- SSTR2 | c.828C>T p.N276= | Silent (SNP) | VAF 13/106 reads (12%) | catalogued as rs151080029; called by muse, mutect2, varscan2
- SUPT20HL1 | c.2583G>T p.V861= | Silent (SNP) | VAF 12/194 reads (6%) | called by muse, mutect2
- TLX2 | c.789G>A p.Q263= | Silent (SNP) | VAF 10/13 reads (77%) | catalogued as rs1355403924; called by muse, mutect2
- AP000769.3 | chr11:65504599 A>G | 5'Flank (SNP) | VAF 142/1118 reads (13%) | called by mutect2, varscan2
- DTNBP1 | c.811+33G>C | Intron (SNP) | VAF 100/256 reads (39%) | catalogued as COSV100160830; called by muse, mutect2, varscan2
